Somatic mutation profile of tumor specimen 0DSEZK from CCDI case PBCHND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar soft part sarcoma; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 7.9 years (2,872 days).
Specimen 0DSEZK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b88f492-bfc3-49ac-8161-98d16d4a0c62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEYV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1285feee-d2f9-4efc-a6c1-22711dc11db0

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASCC3 | c.4696C>G p.R1566G | Missense Mutation (SNP) | VAF 342/1864 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs757716813, COSV64972526; called by muse, varscan2
- NCAPD3 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 164/1672 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV73258060; called by muse, varscan2
- TTC26 | c.1313A>T p.Y438F | Missense Mutation (SNP) | VAF 154/892 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.681); called by muse, varscan2
- CREB3 | c.129+33G>A | Intron (SNP) | VAF 96/548 reads (18%) | called by muse, varscan2
